Somatic mutation profile of tumor specimen TCGA-97-8547-01A (aliquot TCGA-97-8547-01A-11D-2393-08) from TCGA case TCGA-97-8547, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 78.9 years (28,801 days).
Specimen TCGA-97-8547-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a5fb9c5-bc52-4c7f-a65f-8660e7fca8d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-8547-10A (Blood Derived Normal), aliquot TCGA-97-8547-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbf056f2-8cd3-4ad1-83a1-608f41362823

The open-access MAF lists 58 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 11, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 1, In Frame Del 1, Intron 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 50/143 reads (35%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 10/91 reads (11%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ABCA12 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as COSV99792551; called by muse, mutect2, varscan2
- ALS2 | c.3559A>G p.N1187D | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV99970189; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2424A>T p.Q808H | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.986); catalogued as COSV99784778; called by muse, mutect2, varscan2
- ANKRD12 | c.4965G>A p.M1655I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100042284, COSV50824112; called by muse, mutect2, varscan2
- ATL3 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100220018; called by muse, mutect2, varscan2
- BACH1 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1569017478, COSV54517670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL9L | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs757310824, COSV100600291; called by muse, mutect2, varscan2
- BCR | c.448A>G p.S150G | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV100007198; called by muse, mutect2, varscan2
- BDH2 | c.512G>T p.R171M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99600836; called by muse, mutect2, varscan2
- CEP72 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769614223, COSV99375398; called by muse, mutect2, varscan2
- CNTNAP2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs747286104, COSV100666387, COSV100673833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A2 | c.1215G>T p.E405D | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.967); catalogued as COSV100847531; called by muse, mutect2, varscan2
- CPA4 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs748649596, COSV99745434; called by muse, mutect2, varscan2
- CSMD3 | c.7149dup p.V2384Cfs*22 (on ENST00000297405 / NM_001363185.1; = p.V2280Cfs*22 on NM_052900.3) | Frame Shift Ins (INS) | VAF 23/87 reads (26%) | catalogued as rs1230860045; called by mutect2, pindel, varscan2
- FAM50A | c.585G>C p.K195N | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99341247; called by muse, mutect2
- GAB4 | c.1468C>A p.L490I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101272119; called by muse, mutect2, varscan2
- GALNT18 | c.429G>T p.G143= | Splice Region (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99926152; called by muse, mutect2
- HELQ | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99788220; called by muse, mutect2, varscan2
- HYDIN | c.6662G>A p.R2221Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201209591, COSV59261776; called by muse, mutect2, varscan2
- KCNK18 | c.302G>C p.W101S | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100571955, COSV100572164; called by muse, mutect2, varscan2
- KIF1A | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs1373179079, COSV57486101; called by muse, mutect2, varscan2
- LCE2A | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs371565593; called by muse, mutect2
- MAP2K4 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.069); catalogued as rs753665559, COSV62255655; called by muse, mutect2, varscan2
- MUC16 | c.1175G>A p.S392N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); catalogued as rs1379998533, COSV101202133; called by muse, mutect2, varscan2
- OTUD6A | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760055968, COSV57974553; called by muse, mutect2, varscan2
- P2RX3 | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV99629042; called by muse, mutect2, varscan2
- PASD1 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs375505833, COSV100949453; called by muse, mutect2, varscan2
- PCLO | c.10057G>A p.E3353K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as rs765909527, COSV100439225; called by muse, mutect2, varscan2
- PDP2 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs376435687; called by muse, mutect2, varscan2
- PER1 | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs771822030, COSV100424939; called by muse, mutect2, varscan2
- PKD1L1 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 161/333 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1359457723, COSV56966037; called by muse, mutect2, varscan2
- PPM1J | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs759146840, COSV99588583; called by muse, mutect2, varscan2
- RASGEF1C | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1277791700, COSV100745754, COSV63179536; called by muse, mutect2, varscan2
- RHOJ | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV57459577; called by muse, mutect2, varscan2
- RNF113A | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 82/265 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101007137; called by muse, mutect2, varscan2
- SHANK1 | c.1853G>A p.S618N | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.029); catalogued as rs952918765, COSV99522257; called by muse, mutect2
- SLC9C2 | c.1241C>G p.S414* | Nonsense Mutation (SNP) | VAF 31/141 reads (22%) | catalogued as COSV62944851, COSV62945360, COSV62947526; called by muse, mutect2, varscan2
- STON1 | c.1321C>G p.Q441E | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs1178498942, COSV100562363; called by muse, mutect2, varscan2
- VNN2 | c.1115G>C p.R372T | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV100426985; called by muse, mutect2, varscan2
- ZNF135 | c.404G>T p.W135L (on ENST00000313434 / NM_001289401.2; = p.W147L on NM_003436.4) | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100536987; called by muse, mutect2
- ZNF592 | c.983C>A p.S328* | Nonsense Mutation (SNP) | VAF 38/160 reads (24%) | catalogued as COSV100246179; called by muse, mutect2, varscan2
- ZNF592 | c.1082C>A p.S361* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100245626, COSV55439627; called by muse, mutect2, varscan2
- CRYBG1 | c.2709del p.V904Cfs*23 | Frame Shift Del (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- SAMD14 | c.1215_1227dup p.R410Efs*47 (on ENST00000330175 / NM_001257359.2; = p.R438Efs*47 on NM_174920.4) | Frame Shift Ins (INS) | VAF 28/107 reads (26%) | called by mutect2, varscan2
- BCL2L1 | c.663C>T p.A221= (on ENST00000307677 / NM_001317919.2; = p.A158= on NM_001191.4) | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs543917106, COSV100304767; called by muse, mutect2, varscan2
- C20orf96 | c.681C>T p.S227= (on ENST00000360321 / NM_153269.3; = p.S226= on NM_080571.1) | Silent (SNP) | VAF 77/285 reads (27%) | catalogued as COSV100826881; called by muse, mutect2, varscan2
- HYDIN | c.15354G>T p.G5118= | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as COSV101125261; called by muse, mutect2, varscan2
- MATN2 | c.279C>T p.V93= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as COSV99647336; called by muse, mutect2
- MRPS30 | c.1062T>G p.P354= | Silent (SNP) | VAF 145/266 reads (55%) | catalogued as COSV99138187; called by muse, mutect2, varscan2
- NCSTN | c.960C>T p.T320= | Silent (SNP) | VAF 24/141 reads (17%) | catalogued as COSV99667748; called by muse, mutect2, varscan2
- OR51A7 | c.723C>T p.V241= | Silent (SNP) | VAF 37/197 reads (19%) | catalogued as COSV100834779; called by muse, mutect2, varscan2
- PHLDB1 | c.366G>A p.L122= | Silent (SNP) | VAF 49/155 reads (32%) | catalogued as rs1555099496, COSV100616866; called by muse, mutect2, varscan2
- PJA1 | c.249G>A p.E83= | Silent (SNP) | VAF 47/150 reads (31%) | catalogued as COSV100824845; called by muse, mutect2, varscan2
- SLC4A1 | c.792C>T p.F264= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as rs1230209152, COSV99293758; called by muse, mutect2
- TTYH1 | c.225C>T p.P75= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs144710284; called by muse, mutect2
- AL359922.1 | c.348-35294C>T | Intron (SNP) | VAF 7/29 reads (24%) | catalogued as CM112061, CM112062, CS021185, COSV64265217, COSV64265629, COSV64269377; called by muse, mutect2, varscan2
